Somatic mutation profile of tumor specimen TCGA-21-1070-01A (aliquot TCGA-21-1070-01A-01D-1521-08) from TCGA case TCGA-21-1070, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 61.0 years (22,273 days).
Specimen TCGA-21-1070-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f35de2a-f221-4ac3-94f7-c1c95c311628.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-21-1070-11A (Solid Tissue Normal), aliquot TCGA-21-1070-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79f7a9ae-9a03-4b06-af3f-ca2aac0c4b47

The open-access MAF lists 577 somatic variants for this specimen: 453 protein-altering or splice-affecting, 108 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 393, Silent 108, Nonsense Mutation 29, Splice Site 14, Frame Shift Del 12, Intron 8, RNA 6, In Frame Del 1, Frame Shift Ins 1, Splice Region 1, Translation Start Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1216-16_1216-1del p.X406_splice | Splice Site (DEL) | VAF 19/132 reads (14%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- TP53 | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 19/84 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.1266G>A p.R422= | Splice Region (SNP) | VAF 14/68 reads (21%) | catalogued as COSV59385488; called by muse, mutect2, varscan2
- AADACL4 | c.1097G>C p.R366P | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376400654, COSV66106145; called by muse, mutect2
- ABCA13 | c.9779C>A p.S3260Y | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV71286429; called by muse, mutect2, varscan2
- ABCC2 | c.1032-1G>T p.X344_splice | Splice Site (SNP) | VAF 148/659 reads (22%) | catalogued as COSV64970586, COSV64970782; called by muse, mutect2, varscan2
- ABCG8 | c.1315G>T p.G439W | Missense Mutation (SNP) | VAF 334/861 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55392462; called by muse, mutect2, varscan2
- AC105001.2 | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV59108942; called by muse, mutect2
- AC105001.2 | c.136G>T p.G46W | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59108951; called by muse, mutect2
- ACER2 | c.640T>A p.W214R | Missense Mutation (SNP) | VAF 70/260 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61820673; called by muse, mutect2, varscan2
- ACTC1 | c.199C>A p.L67M | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.973); catalogued as COSV51758673; called by muse, mutect2, varscan2
- ACTL6A | c.476+1G>T p.X159_splice | Splice Site (SNP) | VAF 108/715 reads (15%) | catalogued as COSV66998876; called by muse, mutect2, varscan2
- ACTN4 | c.1400A>G p.Q467R | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV53145221; called by muse, mutect2, varscan2
- ACTRT1 | c.344C>A p.P115H | Missense Mutation (SNP) | VAF 161/872 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64419229, COSV64419284; called by muse, varscan2
- ACVR1C | c.718C>A p.Q240K | Missense Mutation (SNP) | VAF 50/252 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV54645602; called by muse, varscan2
- ADAM18 | c.1313C>T p.T438I | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.806); catalogued as rs1407646764, COSV55846408; called by muse, mutect2
- ADAM23 | c.2252G>T p.C751F | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52213024; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3038G>T p.R1013M | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99717632; called by muse, mutect2, varscan2
- ADARB2 | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as COSV67221075; called by muse, mutect2, varscan2
- ADGRE3 | c.1460C>A p.P487H | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.501); catalogued as COSV53730066; called by muse, mutect2, varscan2
- ALPK1 | c.2494T>A p.S832T | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV51584211; called by muse, varscan2
- ALPK1 | c.2495C>A p.S832Y | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.467); catalogued as COSV51584218, COSV51589939; called by muse, varscan2
- AMER1 | c.2088G>C p.R696S | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.549); catalogued as COSV57654356, COSV57659417; called by muse, mutect2, varscan2
- ANAPC5 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1475551358, COSV55842462; called by muse, mutect2, varscan2
- ANGPTL3 | c.587T>A p.I196K | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52002892; called by muse, mutect2, varscan2
- ANK3 | c.12431G>C p.R4144T (on ENST00000280772 / NM_001320874.2; = p.R665T on NM_001149.3) | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV55054205; called by muse, mutect2, varscan2
- ANKRD35 | c.2716G>C p.E906Q | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as COSV62910111; called by muse, mutect2, varscan2
- ANO4 | c.1900C>A p.L634I (on ENST00000392977 / NM_001286615.2; = p.L599I on NM_178826.4) | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.733); catalogued as rs1405028889, COSV54593239; called by muse, mutect2, varscan2
- ANXA10 | c.781C>A p.H261N | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV63738200; called by muse, mutect2, varscan2
- APLF | c.1298A>T p.Q433L | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58144203; called by muse, mutect2, varscan2
- APOB | c.2577G>C p.K859N | Missense Mutation (SNP) | VAF 25/235 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51932522, COSV51944092; called by muse, mutect2, varscan2
- AREL1 | c.646C>G p.H216D | Missense Mutation (SNP) | VAF 56/211 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV62666202, COSV62666697; called by muse, varscan2
- ARHGAP12 | c.1907G>T p.R636L | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV60962777; called by muse, mutect2, varscan2
- ARMC4 | c.2122G>T p.D708Y | Missense Mutation (SNP) | VAF 49/224 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.414); catalogued as COSV100536672, COSV59461933; called by muse, mutect2, varscan2
- ASB12 | c.553C>A p.L185I | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62856598; called by muse, mutect2, varscan2
- ASB9 | c.508C>A p.P170T | Missense Mutation (SNP) | VAF 73/287 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV66851627; called by muse, mutect2, varscan2
- ASTN2 | c.1714C>A p.L572M (on ENST00000313400 / NM_001365069.1; = p.L521M on NM_014010.5) | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV57771522; called by muse, mutect2, varscan2
- ATF2 | c.1432A>T p.T478S | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV51368856; called by muse, mutect2, varscan2
- ATG2B | c.4843-1G>T p.X1615_splice | Splice Site (SNP) | VAF 16/145 reads (11%) | catalogued as COSV55890093; called by muse, mutect2
- ATP4B | c.5C>G p.A2G | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58928819; called by muse, mutect2, varscan2
- ATP8B4 | c.1163A>T p.Y388F | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.224); catalogued as COSV52713811; called by muse, mutect2, varscan2
- ATRNL1 | c.3324C>G p.Y1108* | Nonsense Mutation (SNP) | VAF 22/113 reads (19%) | catalogued as COSV58084183; called by muse, mutect2, varscan2
- ATRX | c.2058G>T p.K686N | Missense Mutation (SNP) | VAF 200/669 reads (30%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV64875138; called by muse, mutect2, varscan2
- BARD1 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV53611217; called by muse, varscan2
- BBS7 | c.1619G>A p.C540Y | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV52655955; called by muse, mutect2, varscan2
- BBX | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 72/283 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs771614227, COSV57882938; called by muse, mutect2, varscan2
- BCORL1 | c.2045C>G p.S682C | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV54394717; called by muse, mutect2, varscan2
- BIRC6 | c.13096C>G p.Q4366E | Missense Mutation (SNP) | VAF 9/224 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs962851082, COSV70198326; called by muse, mutect2
- BIVM-ERCC5 | c.3925G>T p.A1309S | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63244835; called by muse, mutect2, varscan2
- BMPR1A | c.173T>A p.F58Y | Missense Mutation (SNP) | VAF 42/344 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.315); catalogued as COSV63135099; called by muse, mutect2, varscan2
- BPIFB4 | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64951062; called by muse, mutect2, varscan2
- BPIFC | c.188G>T p.S63I | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV55912042; called by muse, mutect2, varscan2
- BRINP2 | c.128C>A p.P43H | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV100837929; called by muse, mutect2, varscan2
- BRINP3 | c.364C>A p.Q122K | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as rs779280815, COSV66521061; called by muse, mutect2, varscan2
- BRPF1 | c.3566A>T p.Q1189L | Missense Mutation (SNP) | VAF 94/277 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV57352528; called by muse, varscan2
- BRWD3 | c.1746C>A p.H582Q | Missense Mutation (SNP) | VAF 62/231 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64747017; called by muse, mutect2, varscan2
- BTLA | c.123G>T p.K41N | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as COSV57938158, COSV57938330; called by muse, mutect2, varscan2
- BUB1B | c.208A>T p.T70S | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55011888; called by muse, varscan2
- C1orf94 | c.1225C>A p.P409T (on ENST00000488417 / NM_001134734.2; = p.P219T on NM_032884.5) | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as COSV64913793; called by muse, mutect2, varscan2
- C7 | c.2236C>A p.H746N | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.912); catalogued as COSV100496768, COSV57473507; called by muse, mutect2, varscan2
- C9 | c.1343C>A p.T448N | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV54676221; called by muse, mutect2, varscan2
- C9orf131 | c.2688C>G p.S896R | Missense Mutation (SNP) | VAF 136/547 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV56610205, COSV56610678; called by muse, mutect2, varscan2
- C9orf78 | c.504G>C p.Q168H | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100204121, COSV59613145; called by muse, mutect2, varscan2
- CACNA1F | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.046); catalogued as COSV59904061; called by muse, mutect2, varscan2
- CADM2 | c.943+1G>T p.X315_splice (on ENST00000407528 / NM_001167674.2; = p.X317_splice on NM_153184.4) | Splice Site (SNP) | VAF 57/144 reads (40%) | catalogued as COSV67369529; called by muse, mutect2, varscan2
- CARD6 | c.1023G>T p.R341S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54564618, COSV54565761; called by muse, mutect2, varscan2
- CARMIL3 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.968); catalogued as rs370361215; called by muse, mutect2, varscan2
- CASR | c.548T>A p.F183Y | Missense Mutation (SNP) | VAF 96/390 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.743); catalogued as COSV56136730; called by muse, mutect2, varscan2
- CCDC85A | c.1076C>G p.P359R | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV68149878; called by muse, mutect2, varscan2
- CCNB3 | c.3957C>G p.Y1319* | Nonsense Mutation (SNP) | VAF 14/72 reads (19%) | catalogued as COSV52072477; called by muse, mutect2, varscan2
- CD164L2 | c.91A>T p.K31* | Nonsense Mutation (SNP) | VAF 25/58 reads (43%) | catalogued as COSV64995628; called by muse, mutect2, varscan2
- CD207 | c.235C>G p.Q79E | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV69651972; called by muse, mutect2, varscan2
- CDH18 | c.2095C>G p.P699A | Missense Mutation (SNP) | VAF 46/245 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV56916381, COSV56922528; called by muse, mutect2, varscan2
- CDH23 | c.7568C>G p.P2523R | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV56458782, COSV56462271; called by muse, mutect2, varscan2
- CDHR5 | c.1537G>T p.G513W (on ENST00000358353 / NM_001171968.2; = p.G519W on NM_021924.5) | Missense Mutation (SNP) | VAF 64/240 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57642212, COSV57642458, COSV57645750; called by muse, varscan2
- CDK18 | c.760A>T p.S254C (on ENST00000506784 / NM_212503.3; = p.S224C on NM_002596.4) | Missense Mutation (SNP) | VAF 84/381 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV63727243; called by muse, mutect2, varscan2
- CEACAM20 | c.125C>A p.T42N | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV57601464; called by muse, mutect2, varscan2
- CEP89 | c.1566-2A>T p.X522_splice | Splice Site (SNP) | VAF 77/316 reads (24%) | catalogued as rs993705365, COSV59863685; called by muse, mutect2, varscan2
- CERKL | c.884G>C p.G295A (on ENST00000339098 / NM_001030311.2; = p.G269A on NM_201548.5) | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59206708; called by muse, mutect2
- CERS2 | c.263A>G p.Y88C | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs777928416, COSV54981110; called by muse, mutect2, varscan2
- CFAP61 | c.1714A>G p.K572E | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV55626633; called by muse, mutect2, varscan2
- CFAP61 | c.3226C>A p.L1076I | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55626643; called by muse, mutect2, varscan2
- CHAT | c.1879C>G p.L627V | Missense Mutation (SNP) | VAF 46/220 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60323775; called by muse, mutect2, varscan2
- CHD9 | c.5378A>T p.Q1793L | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV54609603; called by muse, mutect2, varscan2
- CHRNA1 | c.113T>A p.V38E | Missense Mutation (SNP) | VAF 45/419 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV53682648; called by muse, mutect2, varscan2
- CHRNA4 | c.522C>A p.N174K | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV64719148; called by muse, mutect2, varscan2
- CITED2 | c.669C>G p.I223M | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100863130, COSV62726395; called by muse, mutect2, varscan2
- CLPTM1 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 44/206 reads (21%) | catalogued as COSV61611687; called by muse, mutect2, varscan2
- CNTNAP5 | c.2041C>A p.H681N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.098); catalogued as COSV70482695; called by muse, mutect2, varscan2
- COL12A1 | c.3767A>C p.H1256P | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV59394270; called by muse, mutect2, varscan2
- COL24A1 | c.1843G>A p.G615S | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1204714428, COSV65305104, COSV65312329; called by muse, mutect2, varscan2
- COL24A1 | c.1735G>A p.G579R | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100993309, COSV65305107; called by muse, mutect2
- COL4A5 | c.1532C>A p.P511H | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV60360194; called by muse, mutect2, varscan2
- COL6A2 | c.2566G>T p.V856L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.888); catalogued as COSV52424872; called by muse, mutect2, varscan2
- COX7A2L | c.50C>A p.A17D | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.575); catalogued as COSV52243040; called by muse, mutect2
- CP | c.436G>T p.D146Y | Missense Mutation (SNP) | VAF 70/245 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52830172; called by muse, mutect2, varscan2
- CPN1 | c.919C>A p.L307M | Missense Mutation (SNP) | VAF 152/608 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as COSV64942194; called by muse, varscan2
- CPN1 | c.623A>G p.N208S | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.853); catalogued as COSV64942195; called by muse, mutect2, varscan2
- CPS1 | c.2688-1G>A p.X896_splice | Splice Site (SNP) | VAF 25/150 reads (17%) | catalogued as COSV51808119; called by muse, mutect2, varscan2
- CSMD2 | c.10129G>T p.G3377C | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53904073; called by muse, mutect2, varscan2
- CSMD2 | c.10128G>T p.K3376N | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.098); catalogued as COSV99587419; called by muse, mutect2, varscan2
- CSMD2 | c.7654A>T p.K2552* | Nonsense Mutation (SNP) | VAF 70/187 reads (37%) | catalogued as COSV53904093; called by muse, mutect2, varscan2
- CSMD3 | c.9824G>A p.G3275E (on ENST00000297405 / NM_001363185.1; = p.G3106E on NM_052900.3) | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV52158742, COSV99835522; called by muse, mutect2, varscan2
- CSMD3 | c.9823G>T p.G3275W (on ENST00000297405 / NM_001363185.1; = p.G3106W on NM_052900.3) | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52276628; called by muse, mutect2, varscan2
- CSMD3 | c.4009G>T p.G1337W (on ENST00000297405 / NM_001363185.1; = p.G1233W on NM_052900.3) | Missense Mutation (SNP) | VAF 50/231 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV99828549; called by muse, mutect2, varscan2
- CSMD3 | c.3281C>A p.T1094K (on ENST00000297405 / NM_001363185.1; = p.T990K on NM_052900.3) | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV52158763; called by muse, mutect2, varscan2
- CUL4B | c.574G>C p.G192R | Missense Mutation (SNP) | VAF 56/262 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.56); catalogued as COSV60686790; called by muse, mutect2, varscan2
- CYP2F1 | c.475A>G p.K159E | Missense Mutation (SNP) | VAF 63/288 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV58527224; called by muse, mutect2, varscan2
- CYSLTR1 | c.629C>A p.T210K | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV64819942; called by muse, mutect2, varscan2
- DACT1 | c.1087A>T p.N363Y | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs768116433, COSV60020451; called by muse, mutect2, varscan2
- DCBLD1 | c.1591G>A p.D531N | Missense Mutation (SNP) | VAF 46/203 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV51640178; called by muse, mutect2, varscan2
- DCBLD2 | c.292G>T p.V98F | Missense Mutation (SNP) | VAF 87/393 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58788995; called by muse, mutect2, varscan2
- DCHS1 | c.3403G>T p.G1135* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV55034308; called by muse, mutect2, varscan2
- DHX30 | c.519T>G p.I173M (on ENST00000445061 / NM_138615.3; = p.I134M on NM_014966.3) | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.703); catalogued as COSV62394271, COSV62396183; called by muse, mutect2, varscan2
- DHX37 | c.3088G>T p.G1030W | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100439095; called by muse, mutect2, varscan2
- DLD | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 51/222 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV52737671; called by muse, mutect2, varscan2
- DLGAP1 | c.1747C>A p.Q583K | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.69); catalogued as COSV59798716; called by muse, mutect2, varscan2
- DMBT1 | c.3172G>T p.D1058Y (on ENST00000338354 / NM_001377530.1; = p.D559Y on NM_004406.3) | Missense Mutation (SNP) | VAF 91/370 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57541397; called by muse, mutect2, varscan2
- DMD | c.11014+1G>T p.X3672_splice | Splice Site (SNP) | VAF 38/137 reads (28%) | catalogued as COSV58905629; called by muse, mutect2, varscan2
- DNAH3 | c.7615G>A p.E2539K | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV54516750; called by muse, mutect2, varscan2
- DNAH7 | c.7432A>G p.I2478V | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56760786; called by muse, mutect2, varscan2
- DNAH7 | c.4956G>T p.M1652I | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as COSV56760795; called by muse, mutect2, varscan2
- DNAJB2 | c.34C>G p.R12G | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV60676419, COSV60677461; called by muse, mutect2
- DPH2 | c.136G>T p.G46W | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as COSV52543227; called by muse, mutect2, varscan2
- DPRX | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 68/335 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV64949386; called by muse, mutect2, varscan2
- DPYSL5 | c.760G>C p.G254R | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV56511034; called by muse, mutect2
- DRP2 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 111/433 reads (26%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.011); catalogued as COSV65809162; called by muse, mutect2, varscan2
- DSC1 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57144592; called by muse, mutect2, varscan2
- DSP | c.7389G>T p.K2463N | Missense Mutation (SNP) | VAF 81/200 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65792389; called by muse, mutect2, varscan2
- DUSP13 | c.134T>C p.L45P | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57814134; called by muse, mutect2, varscan2
- DYSF | c.4219G>T p.D1407Y | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50269067, COSV50300200; called by muse, mutect2, varscan2
- EMG1 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54641717; called by muse, mutect2, varscan2
- ENPEP | c.2391G>T p.E797D | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); catalogued as COSV54449783; called by muse, mutect2, varscan2
- ENPP1 | c.1179G>C p.L393F | Missense Mutation (SNP) | VAF 45/225 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62931862; called by muse, mutect2, varscan2
- EPHA1 | c.397G>T p.V133L | Missense Mutation (SNP) | VAF 108/296 reads (36%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.994); catalogued as COSV51970621; called by muse, mutect2, varscan2
- EPS15 | c.2308G>T p.A770S | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV65541788; called by muse, mutect2
- ETV5 | c.1246G>T p.A416S | Missense Mutation (SNP) | VAF 89/213 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60501234; called by muse, mutect2, varscan2
- EVC2 | c.2389G>T p.D797Y | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV60391930; called by muse, mutect2, varscan2
- FAM110B | c.625G>C p.V209L | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as COSV64064672; called by muse, mutect2, varscan2
- FAM131B | c.615A>T p.E205D | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV58369254; called by muse, mutect2, varscan2
- FAM135A | c.3748C>G p.L1250V (on ENST00000370479 / NM_001351599.1; = p.L1037V on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/235 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52050312; called by muse, mutect2, varscan2
- FASTKD3 | c.288T>G p.N96K | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT tolerated (0.93); PolyPhen benign (0.024); catalogued as COSV52942961; called by muse, mutect2, varscan2
- FBN3 | c.4271G>T p.G1424V | Missense Mutation (SNP) | VAF 73/204 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV54458753; called by muse, mutect2, varscan2
- FBXO11 | c.287A>G p.N96S (on ENST00000403359 / NM_001190274.2; = p.N12S on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/268 reads (16%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as COSV57018641; called by muse, mutect2, varscan2
- FCGBP | c.6529G>A p.V2177M | Missense Mutation (SNP) | VAF 32/333 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as rs1181929438, COSV99661473; called by muse, mutect2
- FER1L5 | c.4755C>A p.F1585L (on ENST00000623019; = p.F1558L on NM_001293083.2) | Missense Mutation (SNP) | VAF 117/523 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV67606012; called by muse, mutect2, varscan2
- FGD1 | c.1994G>T p.R665L | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV64308291, COSV64308548; called by muse, mutect2, varscan2
- FGD3 | c.1999G>T p.D667Y | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV61596897; called by muse, mutect2, varscan2
- FLG2 | c.1792T>A p.S598T | Missense Mutation (SNP) | VAF 169/703 reads (24%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.616); catalogued as COSV66168103, COSV66173151; called by muse, mutect2, varscan2
- FLT1 | c.1580C>T p.S527F | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV56725656; called by muse, mutect2, varscan2
- FMC1-LUC7L2 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV52545935; called by muse, varscan2
- FREM1 | c.4136C>A p.P1379H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV101084023; called by muse, mutect2, varscan2
- FSCB | c.110G>A p.S37N | Missense Mutation (SNP) | VAF 56/405 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.629); catalogued as COSV61217652; called by muse, mutect2, varscan2
- GAPVD1 | c.2695C>T p.R899* (on ENST00000394104; = p.R926* on NM_015635.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 40/139 reads (29%) | catalogued as COSV52919951; called by muse, mutect2, varscan2
- GDF3 | c.469G>T p.G157C | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61712234, COSV61713136; called by muse, mutect2, varscan2
- GFRAL | c.389C>A p.S130Y | Missense Mutation (SNP) | VAF 85/417 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV61230371; called by muse, mutect2, varscan2
- GLYATL2 | c.616G>T p.G206C | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1217238835, COSV54849720; called by muse, mutect2, varscan2
- GMNN | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 100/286 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV57776767; called by muse, mutect2, varscan2
- GNB4 | c.992C>A p.S331Y | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51709192; called by muse, mutect2, varscan2
- GNG5 | c.108A>T p.K36N | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.673); catalogued as COSV55362035; called by muse, mutect2, varscan2
- GOLIM4 | c.1169G>T p.R390L | Missense Mutation (SNP) | VAF 154/1098 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.085); catalogued as COSV58329325; called by muse, mutect2, varscan2
- GPD1 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 77/289 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761342764, COSV56547852; called by muse, mutect2, varscan2
- GPR143 | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as COSV66632290; called by muse, mutect2, varscan2
- GPR31 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.166); catalogued as rs1242318594, COSV64761353; called by muse, mutect2, varscan2
- GPR65 | c.286A>C p.M96L | Missense Mutation (SNP) | VAF 143/539 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV50862582; called by muse, mutect2, varscan2
- GRAMD1C | c.1248G>T p.L416F | Missense Mutation (SNP) | VAF 63/272 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV63982571; called by muse, mutect2, varscan2
- GRAMD1C | c.1249G>T p.V417L | Missense Mutation (SNP) | VAF 63/273 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV63982575, COSV63982884; called by muse, mutect2, varscan2
- GRIA1 | c.645G>T p.Q215H | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV53599215; called by muse, mutect2, varscan2
- GRIA3 | c.2431G>T p.D811Y | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV99989428; called by muse, mutect2, varscan2
- GRM4 | c.1816G>T p.V606L | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.994); catalogued as COSV65212587; called by muse, mutect2, varscan2
- GSG1L | c.995G>T p.*332Lext*35 (on ENST00000447459 / NM_001109763.2; = p.*177Lext*35 on NM_144675.2) | Nonstop Mutation (SNP) | VAF 15/71 reads (21%) | catalogued as COSV66577856; called by muse, mutect2, varscan2
- GTF3C2 | c.349C>A p.P117T | Missense Mutation (SNP) | VAF 37/252 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.068); catalogued as COSV53126090; called by muse, mutect2, varscan2
- GUCY2F | c.2472G>T p.M824I | Missense Mutation (SNP) | VAF 85/460 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV54300897; called by muse, mutect2, varscan2
- GUCY2F | c.143T>A p.V48E | Missense Mutation (SNP) | VAF 47/233 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV54300908; called by muse, mutect2, varscan2
- H2AC16 | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 99/269 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV58899781; called by muse, mutect2, varscan2
- HAO1 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV66491751; called by muse, mutect2, varscan2
- HCFC2 | c.908C>A p.S303Y | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.459); catalogued as COSV57558433; called by muse, mutect2
- HCN1 | c.1369C>A p.L457M | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV100298680, COSV57505727; called by muse, mutect2, varscan2
- HDAC9 | c.1439A>C p.Q480P | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV67771666; called by muse, mutect2, varscan2
- HDAC9 | c.2767C>A p.L923I | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67769866; called by muse, mutect2, varscan2
- HERC2 | c.4574G>T p.C1525F | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as COSV99871840; called by muse, mutect2, varscan2
- HGF | c.1130G>T p.C377F | Missense Mutation (SNP) | VAF 83/372 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55948188; called by muse, varscan2
- HRNR | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 166/666 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.514); catalogued as rs1426884760, COSV64257054; called by muse, mutect2, varscan2
- HUWE1 | c.10582G>T p.V3528L | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV53342082, COSV53342708; called by muse, mutect2, varscan2
- HYDIN | c.4204C>T p.H1402Y | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV101141580; called by mutect2, varscan2
- IGFBP6 | c.573C>G p.D191E | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56857257; called by muse, mutect2, varscan2
- IGKV1-8 | c.142G>T p.G48C | Missense Mutation (SNP) | VAF 65/324 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as rs771866000; called by muse, mutect2, varscan2
- IGSF1 | c.1647-1G>C p.X549_splice | Splice Site (SNP) | VAF 26/126 reads (21%) | catalogued as COSV63837072; called by muse, mutect2, varscan2
- IGSF11 | c.938C>T p.S313F (on ENST00000393775 / NM_001015887.3; = p.S312F on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/272 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61168681; called by muse, mutect2, varscan2
- IL20RA | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.11); catalogued as COSV57357795; called by muse, mutect2, varscan2
- IPO9 | c.2293C>T p.R765C | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64233473; called by muse, mutect2, varscan2
- ISX | c.5G>T p.C2F | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV58086301; called by muse, mutect2, varscan2
- ITGAD | c.862G>T p.G288* | Nonsense Mutation (SNP) | VAF 26/73 reads (36%) | catalogued as COSV66757684; called by muse, mutect2, varscan2
- KATNA1 | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs768388071, COSV59502173; called by muse, mutect2, varscan2
- KATNIP | c.1742G>C p.G581A | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.359); catalogued as COSV55178865; called by muse, mutect2, varscan2
- KBTBD12 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59678992; called by muse, mutect2, varscan2
- KCNA5 | c.1624C>A p.Q542K | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.05); catalogued as COSV52903912, COSV52905244; called by muse, mutect2, varscan2
- KCNK10 | c.78C>A p.S26R | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.112); catalogued as COSV56643439; called by muse, varscan2
- KCTD1 | c.249G>T p.M83I | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.042); catalogued as COSV58685495; called by muse, mutect2, varscan2
- KCTD12 | c.228C>G p.S76R | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV58524490; called by muse, mutect2, varscan2
- KHDRBS1 | c.1157A>G p.Y386C | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1179385080, COSV56981747; called by muse, mutect2, varscan2
- KIF5C | c.911G>C p.C304S | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68480811; called by muse, mutect2, varscan2
- KLHL12 | c.233G>C p.G78A | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV63042710; called by muse, mutect2, varscan2
- KLHL22 | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 24/102 reads (24%) | catalogued as COSV61020605; called by muse, varscan2
- KNG1 | c.372G>T p.Q124H | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53977298; called by muse, mutect2, varscan2
- LARGE2 | c.2071G>A p.D691N | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV57652762; called by muse, mutect2, varscan2
- LDHB | c.530A>T p.E177V | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV63364580; called by muse, mutect2, varscan2
- LIG4 | c.2602G>T p.D868Y | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV63596893, COSV63597587; called by muse, mutect2, varscan2
- LILRA2 | c.225G>C p.E75D | Missense Mutation (SNP) | VAF 74/197 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as COSV52190834; called by muse, mutect2, varscan2
- LINGO1 | c.1432C>A p.P478T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as COSV62436799, COSV62439045; called by muse, mutect2, varscan2
- LMO7 | c.293A>G p.N98S (on ENST00000357063; = p.N113S on NM_005358.5) | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751118448, COSV58534331; called by muse, mutect2, varscan2
- LRP1B | c.8945G>T p.C2982F | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs771259326, COSV67199534; called by muse, mutect2, varscan2
- LRR1 | c.98G>A p.C33Y | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV53563258; called by muse, mutect2
- LRRIQ1 | c.3154G>T p.A1052S | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.038); catalogued as COSV67829494, COSV67834868; called by muse, mutect2, varscan2
- LSAMP | c.512C>A p.T171N | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.484); catalogued as COSV61286799; called by muse, mutect2, varscan2
- MAGEA4 | c.943G>T p.E315* | Nonsense Mutation (SNP) | VAF 68/284 reads (24%) | catalogued as COSV52341000, COSV52341324; called by muse, mutect2, varscan2
- MAN2B1 | c.2842A>G p.I948V | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.217); catalogued as COSV55471487; called by muse, mutect2, varscan2
- MAP3K7 | c.634G>T p.V212F | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65224183; called by muse, mutect2, varscan2
- MARF1 | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); catalogued as COSV60022512; called by muse, mutect2, varscan2
- MARK3 | c.1366A>G p.S456G | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV53509428; called by muse, mutect2, varscan2
- MCTS1 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 19/283 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV64892433; called by muse, mutect2
- MERTK | c.2897G>T p.G966V | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV54934701, COSV99774278; called by muse, mutect2, varscan2
- MKRN3 | c.1465G>T p.E489* | Nonsense Mutation (SNP) | VAF 53/312 reads (17%) | catalogued as COSV58809430; called by muse, mutect2, varscan2
- MLPH | c.1732A>T p.R578* | Nonsense Mutation (SNP) | VAF 21/132 reads (16%) | catalogued as COSV52819700; called by muse, mutect2, varscan2
- MMP20 | c.251C>A p.T84N | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52775135; called by muse, mutect2, varscan2
- MMS22L | c.3500A>G p.Y1167C | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as COSV51519980; called by muse, mutect2, varscan2
- MMS22L | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as COSV51519991; called by muse, mutect2, varscan2
- MPV17 | c.11G>T p.W4L | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV51990175; called by muse, mutect2
- MROH2B | c.4266G>A p.W1422* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV68183115; called by muse, mutect2
- MROH2B | c.2545G>T p.G849C | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV68183121; called by muse, mutect2, varscan2
- MROH2B | c.855C>A p.C285* | Nonsense Mutation (SNP) | VAF 13/77 reads (17%) | catalogued as COSV68183125; called by muse, mutect2, varscan2
- MROH9 | c.901A>C p.I301L | Missense Mutation (SNP) | VAF 62/326 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63010917; called by muse, mutect2
- MS4A6E | c.191C>A p.A64D | Missense Mutation (SNP) | VAF 82/355 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55726620; called by muse, mutect2, varscan2
- MTMR8 | c.2024C>A p.A675D | Missense Mutation (SNP) | VAF 64/209 reads (31%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs746078951, COSV66393358; called by muse, mutect2, varscan2
- MUC16 | c.24904C>A p.P8302T | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.067); catalogued as COSV67461200; called by muse, mutect2, varscan2
- MYCT1 | c.290G>T p.R97I | Missense Mutation (SNP) | VAF 49/209 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV65891212; called by muse, mutect2, varscan2
- MYH13 | c.5702G>T p.R1901L | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52825992, COSV52837748, COSV99355915; called by muse, mutect2, varscan2
- MYH15 | c.4057G>T p.D1353Y | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56308400; called by muse, mutect2, varscan2
- MYL2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 39/224 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV57406801; called by muse, mutect2, varscan2
- MYO18B | c.6716C>G p.S2239W | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as rs192136611, COSV100123211, COSV59145660; called by muse, mutect2, varscan2
- MYO7B | c.883G>T p.A295S | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.071); catalogued as COSV67344334, COSV67346872; called by muse, mutect2, varscan2
- NALCN | c.5036T>A p.I1679K | Missense Mutation (SNP) | VAF 66/400 reads (17%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV51930749; called by muse, mutect2, varscan2
- NCKAP1L | c.2021C>A p.T674N | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53205885; called by muse, mutect2, varscan2
- NCOR1 | c.4916A>G p.E1639G | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV51971600; called by muse, mutect2, varscan2
- NCOR1 | c.4915G>T p.E1639* | Nonsense Mutation (SNP) | VAF 14/126 reads (11%) | catalogued as COSV51971624; called by muse, mutect2, varscan2
- NEFM | c.220A>T p.S74C | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55331691; called by muse, mutect2, varscan2
- NELL1 | c.2095G>A p.G699S | Missense Mutation (SNP) | VAF 63/268 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.837); catalogued as rs765086921, COSV54236125, COSV54257333; called by muse, mutect2, varscan2
- NLRP3 | c.1395G>C p.W465C | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as COSV60223025; called by muse, mutect2, varscan2
- NLRP4 | c.1990C>A p.H664N | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV56712228; called by muse, mutect2, varscan2
- NOTCH2 | c.985G>T p.G329C | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99863224; called by muse, mutect2
- NPY2R | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61527922; called by muse, mutect2, varscan2
- NR1H4 | c.466G>T p.G156W (on ENST00000551379 / NM_001206993.2; = p.G146W on NM_005123.4) | Missense Mutation (SNP) | VAF 70/378 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99500221; called by muse, mutect2, varscan2
- NRK | c.1166C>A p.P389H | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV54588712, COSV99688277; called by muse, mutect2, varscan2
- NRXN2 | c.2894T>A p.F965Y | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV55451563; called by muse, mutect2, varscan2
- NUP205 | c.1860A>T p.E620D | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV53657938; called by muse, mutect2, varscan2
- NYX | c.1262T>A p.L421Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61180657; called by muse, mutect2
- OGT | c.2589+1G>T p.X863_splice | Splice Site (SNP) | VAF 52/204 reads (25%) | catalogued as COSV104424950, COSV65480508; called by muse, mutect2, varscan2
- OLFM4 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV54576899; called by muse, mutect2, varscan2
- ONECUT1 | c.1225C>A p.R409S | Missense Mutation (SNP) | VAF 83/277 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59948651, COSV59949668; called by muse, varscan2
- OR10AG1 | c.455G>T p.C152F | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.02); catalogued as COSV56632591; called by muse, mutect2, varscan2
- OR10G9 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 155/521 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); catalogued as rs756357322, COSV66686121, COSV66686718; called by muse, mutect2, varscan2
- OR10J3 | c.544G>T p.V182L | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.378); catalogued as COSV59954180; called by muse, mutect2, varscan2
- OR10K2 | c.866T>C p.I289T | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1557860396, COSV59221059; called by muse, mutect2
- OR2T3 | c.588C>G p.D196E | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV100613006, COSV100613416; called by mutect2, varscan2
- OR2T34 | c.588C>G p.D196E | Missense Mutation (SNP) | VAF 75/651 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV60900244; called by muse, mutect2, varscan2
- OR2T6 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63216093; called by muse, mutect2, varscan2
- OR4A5 | c.702G>T p.L234F | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.521); catalogued as COSV60522282; called by muse, mutect2, varscan2
- OR52N4 | c.383T>A p.I128N | Missense Mutation (SNP) | VAF 67/246 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV57890912; called by muse, mutect2, varscan2
- OR56A3 | c.710C>A p.A237D | Missense Mutation (SNP) | VAF 110/318 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV61568934; called by muse, mutect2, varscan2
- OR5B21 | c.808del p.I270* | Frame Shift Del (DEL) | VAF 64/322 reads (20%) | catalogued as COSV100835143; called by mutect2, pindel, varscan2
- OR6C70 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 56/235 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); catalogued as COSV59244771; called by muse, mutect2, varscan2
- OR6Y1 | c.440G>C p.G147A | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as COSV56929141; called by mutect2, varscan2
- OR7E24 | c.925A>G p.S309G | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV71702190; called by muse, mutect2, varscan2
- OR8D1 | c.326T>A p.V109E | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV63442075; called by muse, mutect2, varscan2
- OR8H2 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 122/572 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.129); catalogued as rs777087856, COSV57944234; called by muse, mutect2, varscan2
- OR8K3 | c.705G>C p.K235N | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57131306, COSV57132387; called by muse, mutect2, varscan2
- OS9 | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 51/196 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57782660; called by muse, mutect2, varscan2
- OSBP | c.320G>T p.R107L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99802800; called by muse, mutect2, varscan2
- OTOP1 | c.1573C>A p.P525T | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV56392567; called by muse, mutect2, varscan2
- OVOL2 | c.598G>T p.V200L | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53860036; called by muse, mutect2, varscan2
- P2RY2 | c.400G>C p.G134R | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60775967, COSV60778104; called by muse, mutect2
- PAK5 | c.1282T>C p.S428P | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as COSV62025765; called by muse, mutect2, varscan2
- PAX1 | c.1451C>G p.T484R | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as COSV68271581, COSV68273810; called by muse, mutect2, varscan2
- PBLD | c.475C>G p.Q159E | Missense Mutation (SNP) | VAF 15/296 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV53265720; called by muse, mutect2
- PCDH11X | c.2059C>A p.P687T | Missense Mutation (SNP) | VAF 68/371 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV53459062; called by muse, mutect2, varscan2
- PCDHA4 | c.1108G>T p.A370S | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as rs1286163937, COSV63540610, COSV63545846; called by muse, mutect2, varscan2
- PCDHB14 | c.490A>T p.S164C | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.778); catalogued as COSV53387962; called by muse, mutect2, varscan2
- PCDHB16 | c.866G>T p.S289I | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.089); catalogued as COSV53361166; called by muse, mutect2, varscan2
- PDE11A | c.2671C>G p.L891V | Missense Mutation (SNP) | VAF 85/257 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV53692322; called by muse, mutect2, varscan2
- PDE1C | c.1829G>T p.G610V | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.034); catalogued as rs773496943, COSV58511052, COSV58511393; called by muse, mutect2
- PDE1C | c.1828G>T p.G610C | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.161); catalogued as COSV58511412; called by muse, mutect2
- PDHX | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 49/228 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV57165605; called by muse, varscan2
- PDYN | c.672G>C p.K224N | Missense Mutation (SNP) | VAF 64/296 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54101576, COSV54102606; called by muse, mutect2, varscan2
- PDZD4 | c.294G>T p.E98D | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.991); catalogued as COSV51246287; called by muse, mutect2, varscan2
- PFKFB1 | c.516G>T p.R172S | Missense Mutation (SNP) | VAF 45/175 reads (26%) | PolyPhen benign (0.184); catalogued as COSV66628146; called by muse, mutect2, varscan2
- PFKFB1 | c.515G>T p.R172M | Missense Mutation (SNP) | VAF 46/177 reads (26%) | PolyPhen benign (0.014); catalogued as COSV66628149; called by muse, mutect2, varscan2
- PHEX | c.875C>A p.T292N | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.031); catalogued as COSV65075046; called by muse, mutect2, varscan2
- PI3 | c.326G>A p.C109Y | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54783135; called by muse, mutect2, varscan2
- PIGO | c.-1-1G>T | Splice Site (SNP) | VAF 14/58 reads (24%) | catalogued as COSV53053397; called by muse, mutect2, varscan2
- PIK3CG | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 51/215 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.034); catalogued as COSV63245630; called by muse, mutect2, varscan2
- PIK3R4 | c.1996C>T p.H666Y | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63240476; called by muse, mutect2, varscan2
- PIM2 | c.112C>A p.L38M | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50234929, COSV50240860; called by muse, mutect2, varscan2
- PKDREJ | c.1246C>A p.L416M | Missense Mutation (SNP) | VAF 76/227 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as COSV53548752; called by muse, mutect2, varscan2
- PKHD1 | c.5567C>A p.S1856* | Nonsense Mutation (SNP) | VAF 58/249 reads (23%) | catalogued as COSV61871639; called by muse, mutect2, varscan2
- PLEC | c.7913G>T p.S2638I (on ENST00000322810 / NM_201380.4; = p.S2528I on NM_000445.5) | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs782359358, COSV59627431; called by muse, mutect2, varscan2
- PNPLA3 | c.701T>C p.L234P | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV53377982; called by muse, mutect2, varscan2
- PPP1R12C | c.365A>T p.E122V | Missense Mutation (SNP) | VAF 54/213 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV54737031; called by muse, mutect2, varscan2
- PPP1R9A | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV56889907; called by muse, mutect2, varscan2
- PRH2 | c.302C>G p.P101R | Missense Mutation (SNP) | VAF 109/457 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV101113297, COSV101113315; called by muse, mutect2, varscan2
- PRKG1 | c.248C>A p.P83H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as COSV100912287; called by muse, mutect2, varscan2
- PTCHD3 | c.416G>A p.W139* | Nonsense Mutation (SNP) | VAF 24/101 reads (24%) | catalogued as COSV71256698; called by muse, mutect2, varscan2
- PTPN13 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.164); catalogued as COSV57406128; called by muse, mutect2, varscan2
- PTPRT | c.3858G>T p.Q1286H | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61975877; called by muse, mutect2, varscan2
- PXDN | c.3521G>T p.R1174M | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99412744; called by muse, mutect2, varscan2
- PXDNL | c.2009A>T p.Q670L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV62485829; called by muse, mutect2, varscan2
- PYHIN1 | c.443G>C p.G148A | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as COSV63722167; called by muse, mutect2, varscan2
- RAB19 | c.621G>C p.Q207H | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV52044433; called by muse, mutect2, varscan2
- RANBP2 | c.4373A>G p.K1458R | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.7); catalogued as COSV51699843; called by muse, mutect2, varscan2
- RAPGEF6 | c.1320A>G p.I440M | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57244719; called by muse, mutect2, varscan2
- RASA1 | c.951G>A p.W317* | Nonsense Mutation (SNP) | VAF 44/150 reads (29%) | catalogued as COSV57194657; called by muse, mutect2, varscan2
- RASAL3 | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as COSV59139193; called by mutect2, varscan2
- RCOR2 | c.536C>T p.T179I | Missense Mutation (SNP) | VAF 67/284 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56849938; called by muse, mutect2, varscan2
- RETSAT | c.1106G>T p.R369L | Missense Mutation (SNP) | VAF 44/243 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as COSV55525207, COSV55525699; called by muse, mutect2, varscan2
- RFTN2 | c.602C>A p.T201K | Missense Mutation (SNP) | VAF 66/387 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.103); catalogued as COSV54387879; called by muse, mutect2, varscan2
- RFX4 | c.831C>A p.D277E (on ENST00000392842 / NM_213594.3; = p.D183E on NM_032491.6) | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.935); catalogued as COSV57575122; called by muse, mutect2, varscan2
- RHOBTB1 | c.1544G>T p.G515V | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as COSV100558374; called by muse, mutect2, varscan2
- RPL10L | c.311C>A p.S104Y | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100022561, COSV53559384; called by muse, mutect2, varscan2
- RPLP0 | c.118A>T p.M40L | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs1224580367, COSV56106725; called by muse, mutect2, varscan2
- RPLP0 | c.117G>T p.Q39H | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56106732; called by muse, mutect2, varscan2
- RPS6KA6 | c.502G>T p.V168F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs1347850032, COSV53118780; called by muse, mutect2, varscan2
- RPTN | c.2347C>A p.Q783K | Missense Mutation (SNP) | VAF 227/1028 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV60167045; called by muse, mutect2, varscan2
- RPUSD4 | c.780G>T p.E260D | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV53599197; called by muse, mutect2, varscan2
- RXFP1 | c.545G>C p.S182T | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.788); catalogued as COSV57049094; called by muse, mutect2
- RXRG | c.677G>A p.C226Y | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs1461075815, COSV63231944; called by muse, mutect2, varscan2
- RYR2 | c.244C>A p.L82M | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV63680246; called by muse, mutect2, varscan2
- RYR2 | c.1236A>T p.E412D | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV63680247; called by muse, mutect2, varscan2
- SCEL | c.1066G>T p.V356L (on ENST00000349847 / NM_144777.3; = p.V336L on NM_003843.4) | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.192); catalogued as COSV62993324; called by muse, mutect2, varscan2
- SCGB2A1 | c.154A>G p.S52G | Missense Mutation (SNP) | VAF 74/302 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV55276061; called by muse, mutect2, varscan2
- SCN9A | c.4154T>A p.L1385Q (on ENST00000303354; = p.L1374Q on NM_002977.3) | Missense Mutation (SNP) | VAF 35/291 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV57607137; called by muse, mutect2, varscan2
- SDHAF3 | c.229G>C p.G77R | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as COSV64490995; called by muse, mutect2, varscan2
- SEMA5A | c.2592G>T p.R864S | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV66790425; called by muse, mutect2, varscan2
- SERPINC1 | c.284A>G p.Y95C | Missense Mutation (SNP) | VAF 106/403 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs907768931, CM940130, CM952084, COSV62929207; called by muse, mutect2, varscan2
- SETDB1 | c.3565G>C p.E1189Q | Missense Mutation (SNP) | VAF 46/546 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.365); catalogued as COSV54981090; called by muse, mutect2
- SFMBT2 | c.1958G>T p.C653F | Missense Mutation (SNP) | VAF 39/313 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62808521; called by muse, mutect2, varscan2
- SFMBT2 | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV100738649, COSV62815777; called by muse, mutect2, varscan2
- SGPL1 | c.412G>T p.A138S | Missense Mutation (SNP) | VAF 37/211 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV54736721, COSV54736797; called by muse, mutect2, varscan2
- SHC2 | c.1606G>T p.D536Y | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52745372; called by muse, varscan2
- SIGLEC1 | c.2054G>T p.G685V | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755506229, COSV52462185; called by muse, mutect2, varscan2
- SLC38A8 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1387496280, COSV55305948, COSV55305998; called by muse, mutect2
- SLC39A4 | c.518C>A p.A173E (on ENST00000301305 / NM_001374839.1; = p.A148E on NM_017767.3) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.111); catalogued as COSV52778563; called by muse, mutect2, varscan2
- SLC44A4 | c.1461A>C p.L487F | Missense Mutation (SNP) | VAF 68/157 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57666898; called by muse, mutect2, varscan2
- SLC44A5 | c.873G>C p.Q291H | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.396); catalogued as COSV63763130; called by muse, mutect2, varscan2
- SLC45A3 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.145); catalogued as COSV65654844; called by muse, mutect2, varscan2
- SLC4A4 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 59/176 reads (34%) | catalogued as COSV52622204; called by muse, mutect2, varscan2
- SLC52A2 | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as rs371806077; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLCO1A2 | c.1912G>T p.E638* | Nonsense Mutation (SNP) | VAF 86/255 reads (34%) | catalogued as COSV56600790; called by muse, mutect2, varscan2
- SLCO1B1 | c.940C>A p.Q314K | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57009944; called by muse, mutect2, varscan2
- SLFN5 | c.748A>T p.S250C | Missense Mutation (SNP) | VAF 66/259 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV104410448, COSV55480793; called by muse, mutect2, varscan2
- SLIT2 | c.2598C>A p.N866K | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV56569200; called by muse, mutect2, varscan2
- SND1 | c.1585G>T p.A529S | Missense Mutation (SNP) | VAF 63/259 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV61239463; called by muse, mutect2, varscan2
- SNX24 | c.374C>A p.S125* | Nonsense Mutation (SNP) | VAF 18/84 reads (21%) | catalogued as COSV54450796; called by muse, varscan2
- SORBS1 | c.1054G>A p.G352S (on ENST00000361941 / NM_001034954.2; = p.G188S on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.001); catalogued as COSV53356326; called by muse, mutect2, varscan2
- SP7 | c.836A>G p.E279G | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV58190789; called by muse, mutect2, varscan2
- SPANXN1 | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.131); catalogued as COSV65122266; called by muse, mutect2, varscan2
- SPTA1 | c.3751G>A p.E1251K | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.688); catalogued as rs771093658, COSV63751987; called by muse, mutect2, varscan2
- STARD8 | c.251G>T p.S84I | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV52925096; called by muse, mutect2, varscan2
- STC1 | c.307G>T p.V103F | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as COSV51688262; called by muse, mutect2, varscan2
- STRN3 | c.1765G>T p.V589F (on ENST00000357479 / NM_001083893.2; = p.V505F on NM_014574.4) | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62579257; called by muse, mutect2, varscan2
- STT3A | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 44/237 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.393); catalogued as COSV67064591; called by muse, mutect2, varscan2
- STX16 | c.620A>T p.D207V (on ENST00000371141 / NM_001001433.3; = p.D186V on NM_003763.6) | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV56605163; called by muse, mutect2, varscan2
- STYXL2 | c.3446G>T p.R1149M | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV54804204; called by muse, mutect2, varscan2
- SUPT7L | c.257A>G p.Q86R | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as COSV58134538; called by muse, mutect2
- SYNE1 | c.14811C>G p.S4937R (on ENST00000367255 / NM_182961.4; = p.S4866R on NM_033071.3) | Missense Mutation (SNP) | VAF 105/498 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54961884; called by muse, mutect2, varscan2
- SYNE1 | c.14810G>A p.S4937N (on ENST00000367255 / NM_182961.4; = p.S4866N on NM_033071.3) | Missense Mutation (SNP) | VAF 104/489 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as rs756252126, COSV54961936; called by muse, mutect2, varscan2
- SYTL2 | c.1255G>T p.G419W | Missense Mutation (SNP) | VAF 41/244 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV100313827, COSV100314544; called by muse, mutect2, varscan2
- SYTL2 | c.693G>T p.K231N | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as COSV60358307; called by muse, mutect2, varscan2
- TAAR1 | c.475A>C p.I159L | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.51); catalogued as COSV51588466, COSV51588641; called by muse, mutect2, varscan2
- TAF1 | c.3067C>T p.P1023S (on ENST00000373790 / NM_138923.4; = p.P1044S on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/214 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as COSV52111680; called by muse, mutect2, varscan2
- TBC1D12 | c.1262A>T p.Y421F | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.841); catalogued as COSV56553673; called by muse, mutect2, varscan2
- TBXA2R | c.628C>A p.L210M | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.273); catalogued as COSV64343524; called by muse, mutect2, varscan2
- TCTN2 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766012866, COSV57632562; called by muse, mutect2, varscan2
- TENM1 | c.4083+1G>T p.X1361_splice | Splice Site (SNP) | VAF 52/232 reads (22%) | catalogued as COSV64430336; called by muse, mutect2, varscan2
- TENM1 | c.261C>A p.Y87* | Nonsense Mutation (SNP) | VAF 90/413 reads (22%) | catalogued as COSV64430349; called by muse, mutect2, varscan2
- TENM4 | c.5836G>A p.E1946K | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53623121; called by muse, mutect2, varscan2
- TEX13A | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as COSV61153300; called by muse, varscan2
- TEX13A | c.207G>T p.W69C | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV100780917, COSV61157268; called by muse, varscan2
- TFCP2L1 | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 30/271 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as COSV99747892; called by muse, mutect2, varscan2
- TFE3 | c.391C>A p.R131S | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV59946616; called by muse, mutect2, varscan2
- TG | c.1693C>G p.L565V | Missense Mutation (SNP) | VAF 56/238 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.056); catalogued as COSV55070588; called by muse, mutect2, varscan2
- TJP1 | c.5206G>T p.V1736F | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369915729; called by muse, mutect2, varscan2
- TLR1 | c.1888G>T p.E630* | Nonsense Mutation (SNP) | VAF 93/260 reads (36%) | catalogued as COSV58304033; called by muse, mutect2, varscan2
- TMEM108 | c.89A>G p.Q30R | Missense Mutation (SNP) | VAF 184/878 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.346); catalogued as COSV58869867; called by muse, mutect2, varscan2
- TMEM132D | c.2815G>C p.V939L | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.352); catalogued as COSV67159961; called by muse, mutect2, varscan2
- TMEM72 | c.95C>G p.T32S | Missense Mutation (SNP) | VAF 37/222 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV67460415; called by muse, mutect2, varscan2
- TNKS | c.2494G>T p.D832Y | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60055937; called by muse, mutect2, varscan2
- TNN | c.2680G>A p.D894N | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.042); catalogued as rs1369127221, COSV53425053; called by muse, mutect2, varscan2
- TNR | c.2279G>C p.R760P | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54868243, COSV54881171; called by muse, mutect2, varscan2
- TOP2A | c.173C>A p.T58N | Missense Mutation (SNP) | VAF 91/360 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV101396101; called by mutect2, varscan2
- TRAM1 | c.44G>T p.S15I | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV51597827; called by muse, mutect2, varscan2
- TRIP13 | c.593T>G p.I198S | Missense Mutation (SNP) | VAF 146/295 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51319723; called by muse, mutect2, varscan2
- TSGA10 | c.618G>T p.L206F | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.743); catalogued as rs376022194, COSV61822998; called by muse, mutect2, varscan2
- TSN | c.141G>T p.Q47H | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.285); catalogued as COSV101067462, COSV67605260; called by muse, mutect2, varscan2
- TSNARE1 | c.1118G>T p.R373M | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV100210052; called by muse, mutect2, varscan2
- TSPYL2 | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV60234533; called by muse, mutect2, varscan2
- TTC16 | c.247C>T p.L83F | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1357462725, COSV58852783; called by muse, mutect2, varscan2
- TTC21B | c.2207T>C p.L736P | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV54629770; called by muse, mutect2, varscan2
- TTN | c.97371C>G p.I32457M (on ENST00000591111; = p.I25033M on NM_003319.4) | Missense Mutation (SNP) | VAF 20/182 reads (11%) | PolyPhen benign (0.318); catalogued as COSV60000672; called by muse, mutect2, varscan2
- TTN | c.60017C>A p.T20006K (on ENST00000591111; = p.T12582K on NM_003319.4) | Missense Mutation (SNP) | VAF 51/465 reads (11%) | PolyPhen benign (0.036); catalogued as COSV60000709; called by muse, mutect2, varscan2
- UGCG | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1046942237, COSV65335804, COSV65336106; called by muse, mutect2, varscan2
- UHRF1BP1L | c.4331T>C p.L1444P | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54436279; called by muse, mutect2, varscan2
- UMODL1 | c.1045G>T p.G349C | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV61159862; called by muse, mutect2, varscan2
- UNC5D | c.1153G>T p.G385C | Missense Mutation (SNP) | VAF 92/398 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54788068; called by muse, mutect2, varscan2
- VAX2 | c.367C>A p.R123S | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as rs782217454, COSV52265708, COSV99313382; called by muse, mutect2, varscan2
- VIRMA | c.4162A>T p.K1388* | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | catalogued as COSV52584267; called by muse, mutect2, varscan2
- VRTN | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV56440426; called by muse, mutect2, varscan2
- VSIG4 | c.431C>A p.T144K | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.241); catalogued as COSV66073596; called by muse, mutect2, varscan2
- WNK3 | c.2716C>A p.P906T | Missense Mutation (SNP) | VAF 71/264 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as COSV63613298; called by muse, mutect2, varscan2
- WRN | c.3107A>G p.K1036R | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.25); catalogued as rs773176431, COSV53299117; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- XPNPEP2 | c.1957C>A p.P653T | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.026); catalogued as COSV100941441; called by muse, mutect2, varscan2
- ZBTB49 | c.1049G>T p.S350I | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.048); catalogued as COSV61924879; called by muse, mutect2, varscan2
- ZFP69 | c.141G>C p.Q47H | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV65528865; called by muse, mutect2
- ZFR | c.1979+1G>A p.X660_splice | Splice Site (SNP) | VAF 78/317 reads (25%) | catalogued as COSV54052376; called by muse, mutect2, varscan2
- ZFYVE26 | c.1801G>T p.E601* | Nonsense Mutation (SNP) | VAF 28/141 reads (20%) | catalogued as COSV61327394; called by muse, mutect2, varscan2
- ZFYVE26 | c.1529C>A p.A510D | Missense Mutation (SNP) | VAF 40/271 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61327412, COSV61328947; called by muse, mutect2, varscan2
- ZNF208 | c.503C>A p.T168N | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); catalogued as COSV68104067; called by muse, mutect2, varscan2
- ZNF33A | c.2332G>T p.E778* (on ENST00000458705 / NM_006974.3; = p.E779* on NM_006954.2) | Nonsense Mutation (SNP) | VAF 25/135 reads (19%) | catalogued as COSV56724472; called by muse, mutect2, varscan2
- ZNF536 | c.3449C>T p.P1150L | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV62822732; called by muse, mutect2, varscan2
- ZNF592 | c.1058G>T p.C353F | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55436319; called by muse, mutect2, varscan2
- ZNF638 | c.1502C>T p.S501L | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV52485577, COSV52493184; called by muse, mutect2
- ZNF711 | c.1633C>A p.Q545K | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV52153293; called by muse, varscan2
- ZNF713 | c.944C>G p.S315C (on ENST00000633730 / NM_001366796.2; = p.S328C on NM_182633.3) | Missense Mutation (SNP) | VAF 64/299 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV70056639; called by muse, mutect2, varscan2
- ZNF746 | c.713-1G>T p.X238_splice | Splice Site (SNP) | VAF 23/68 reads (34%) | catalogued as COSV61407161; called by muse, mutect2, varscan2
- ZP4 | c.1601G>C p.C534S | Missense Mutation (SNP) | VAF 69/314 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV63910959, COSV63911734; called by muse, mutect2, varscan2
- ZSCAN25 | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.134); catalogued as COSV53552798; called by muse, mutect2, varscan2
- ZXDA | c.886G>T p.G296C | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62387860; called by muse, mutect2, varscan2
- AFF4 | c.3241_3244del p.S1081Qfs*2 | Frame Shift Del (DEL) | VAF 28/118 reads (24%) | called by mutect2, pindel, varscan2
- AGTR2 | c.474del p.W158Cfs*6 | Frame Shift Del (DEL) | VAF 137/796 reads (17%) | called by mutect2, pindel, varscan2
- C8orf34 | c.425_443del p.Q142Lfs*29 | Frame Shift Del (DEL) | VAF 19/131 reads (15%) | called by mutect2, pindel, varscan2
- IGHA2 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.747); called by muse, mutect2
- IGKV1D-43 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- IGKV5-2 | c.256G>T p.G86W | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LCE3A | c.115_123del p.C39_P41del | In Frame Del (DEL) | VAF 27/128 reads (21%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.1043G>T p.C348F | Missense Mutation (SNP) | VAF 66/304 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.045); called by muse, varscan2
- MAGEE1 | c.2359del p.L787* | Frame Shift Del (DEL) | VAF 74/357 reads (21%) | called by mutect2, pindel, varscan2
- MAGEL2 | c.3255del p.H1085Qfs*21 | Frame Shift Del (DEL) | VAF 16/90 reads (18%) | called by mutect2, pindel, varscan2
- NBPF9 | c.1333G>C p.V445L | Missense Mutation (SNP) | VAF 126/298 reads (42%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- NOS1 | c.3078del p.S1027Afs*23 | Frame Shift Del (DEL) | VAF 27/104 reads (26%) | called by mutect2, pindel, varscan2
- POP1 | c.297del p.K100Sfs*3 | Frame Shift Del (DEL) | VAF 41/209 reads (20%) | called by mutect2, pindel, varscan2
- RYR2 | c.3804_3805insAA p.E1269Kfs*3 | Frame Shift Ins (INS) | VAF 11/66 reads (17%) | called by mutect2, pindel
- TRAV7 | c.223_225delinsT p.G75Lfs*2 | Frame Shift Del (DEL) | VAF 17/97 reads (18%) | called by pindel, varscan2*
- ZFC3H1 | c.2641del p.I881Ffs*9 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | called by mutect2, pindel, varscan2
- ZNF343 | c.53del p.L18Cfs*9 | Frame Shift Del (DEL) | VAF 63/384 reads (16%) | called by mutect2, pindel, varscan2
- ZNF703 | c.1703del p.G568Dfs*14 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | called by mutect2, pindel, varscan2
- ACTL9 | c.564C>T p.H188= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as COSV61005582; called by muse, mutect2, varscan2
- ALS2CL | c.447G>T p.S149= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs777901252, COSV59671049; called by muse, mutect2
- ANK2 | c.360A>T p.G120= | Silent (SNP) | VAF 36/107 reads (34%) | catalogued as COSV52157157; called by muse, mutect2, varscan2
- AP4M1 | c.33G>A p.K11= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as rs767024160, COSV57995818; called by muse, mutect2, varscan2
- AQP8 | c.612G>T p.V204= | Silent (SNP) | VAF 45/130 reads (35%) | catalogued as COSV54844982, COSV99563755; called by muse, mutect2, varscan2
- ARMCX2 | c.345C>A p.A115= | Silent (SNP) | VAF 54/243 reads (22%) | catalogued as COSV57529787; called by muse, mutect2, varscan2
- ARMCX3 | c.84T>C p.T28= | Silent (SNP) | VAF 70/252 reads (28%) | catalogued as COSV57870193; called by muse, varscan2
- ASTN2 | c.3699G>A p.L1233= (on ENST00000313400 / NM_001365069.1; = p.L1182= on NM_014010.5) | Silent (SNP) | VAF 55/153 reads (36%) | catalogued as COSV56003198, COSV99940429; called by muse, mutect2, varscan2
- ATP8B2 | c.1876C>T p.L626= (on ENST00000672630; = p.L593= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 33/134 reads (25%) | catalogued as COSV59245699; called by muse, mutect2, varscan2
- BRD9 | c.1257G>T p.V419= | Silent (SNP) | VAF 30/375 reads (8%) | catalogued as COSV60246176; called by muse, mutect2
- BRF1 | c.366G>T p.L122= | Silent (SNP) | VAF 61/161 reads (38%) | catalogued as COSV59268093; called by muse, mutect2, varscan2
- C1R | c.807A>T p.L269= (on ENST00000536053 / NM_001354346.2; = p.L255= on NM_001733.7) | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV73293798; called by muse, mutect2, varscan2
- C9 | c.1344C>A p.T448= | Silent (SNP) | VAF 28/191 reads (15%) | catalogued as rs1366887364, COSV54677385, COSV99661865; called by muse, mutect2, varscan2
- CACNA1C | c.4578G>A p.P1526= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs376555924; called by muse, mutect2, varscan2
- CACNA1E | c.1090C>A p.R364= | Silent (SNP) | VAF 28/202 reads (14%) | catalogued as COSV100701529, COSV62390108; called by muse, mutect2, varscan2
- CACNA2D4 | c.846C>T p.Y282= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV54948722; called by muse, mutect2, varscan2
- CALCR | c.30G>A p.L10= | Silent (SNP) | VAF 53/268 reads (20%) | catalogued as COSV64007498; called by muse, mutect2, varscan2
- CAMLG | c.207C>T p.D69= | Silent (SNP) | VAF 36/108 reads (33%) | catalogued as COSV51804565; called by muse, mutect2, varscan2
- CCNB3 | c.3153C>A p.P1051= | Silent (SNP) | VAF 73/324 reads (23%) | catalogued as COSV99328687, COSV99329215; called by muse, mutect2, varscan2
- CDH18 | c.2160G>T p.L720= | Silent (SNP) | VAF 33/171 reads (19%) | catalogued as COSV56916371; called by muse, mutect2, varscan2
- CDH8 | c.1461G>A p.L487= | Silent (SNP) | VAF 81/265 reads (31%) | catalogued as COSV54861977, COSV54901567; called by muse, mutect2, varscan2
- CDHR1 | c.1533C>A p.T511= | Silent (SNP) | VAF 86/339 reads (25%) | catalogued as COSV60561632; called by muse, mutect2, varscan2
- CHRM2 | c.993C>G p.T331= | Silent (SNP) | VAF 37/152 reads (24%) | catalogued as COSV57770006; called by muse, mutect2, varscan2
- CLPTM1 | c.696G>T p.V232= | Silent (SNP) | VAF 44/203 reads (22%) | catalogued as COSV61611678; called by muse, mutect2, varscan2
- COL6A6 | c.5385C>A p.P1795= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100650345; called by mutect2, varscan2
- CTNND1 | c.114G>T p.S38= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV100649935, COSV62386736; called by muse, mutect2, varscan2
- CYSLTR2 | c.520C>T p.L174= | Silent (SNP) | VAF 73/239 reads (31%) | catalogued as COSV56165632; called by muse, mutect2, varscan2
- DCAF8L1 | c.1005C>A p.V335= | Silent (SNP) | VAF 51/186 reads (27%) | catalogued as COSV71595240; called by muse, mutect2, varscan2
- DCAF8L1 | c.603C>A p.T201= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV71595242; called by muse, mutect2, varscan2
- DDX53 | c.1797A>T p.V599= | Silent (SNP) | VAF 44/188 reads (23%) | catalogued as COSV60068884; called by muse, mutect2, varscan2
- DLGAP1 | c.1746C>T p.S582= | Silent (SNP) | VAF 50/172 reads (29%) | catalogued as COSV59798749; called by muse, mutect2, varscan2
- DOCK9 | c.4143G>T p.S1381= (on ENST00000376460 / NM_001366676.2; = p.S1382= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV100237360, COSV100238397; called by muse, mutect2, varscan2
- DYNC1H1 | c.5490T>C p.I1830= | Silent (SNP) | VAF 54/371 reads (15%) | catalogued as COSV64136267; called by muse, mutect2, varscan2
- FARP1 | c.3039C>T p.S1013= | Silent (SNP) | VAF 46/191 reads (24%) | catalogued as rs1376770800, COSV60330215; called by muse, mutect2, varscan2
- FIBCD1 | c.411G>T p.L137= | Silent (SNP) | VAF 8/16 reads (50%) | called by muse, varscan2
- GAL3ST1 | c.462G>A p.P154= | Silent (SNP) | VAF 54/216 reads (25%) | catalogued as rs746563784, COSV58892382; called by muse, mutect2, varscan2
- GNAS | c.222A>G p.E74= | Silent (SNP) | VAF 21/275 reads (8%) | catalogued as COSV55671776, COSV55674711; called by muse, mutect2
- GPRASP1 | c.75G>T p.G25= | Silent (SNP) | VAF 104/455 reads (23%) | catalogued as COSV64355407; called by muse, mutect2, varscan2
- GZMB | c.66C>T p.I22= | Silent (SNP) | VAF 56/368 reads (15%) | catalogued as rs139103546; called by muse, mutect2, varscan2
- H3C4 | c.399G>C p.G133= | Silent (SNP) | VAF 10/140 reads (7%) | catalogued as COSV61911828; called by muse, mutect2
- HAS1 | c.963T>A p.L321= | Silent (SNP) | VAF 14/162 reads (9%) | catalogued as COSV55787120; called by muse, mutect2
- HCN1 | c.2341C>A p.R781= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as COSV100299291, COSV100303082; called by muse, mutect2, varscan2
- HUWE1 | c.10581C>T p.V3527= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as rs369048914, COSV53342728; called by muse, mutect2, varscan2
- ICE1 | c.4446G>A p.E1482= | Silent (SNP) | VAF 147/330 reads (45%) | catalogued as rs566445452, COSV56823022; called by muse, mutect2, varscan2
- IL18R1 | c.360C>T p.F120= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as rs750592389, COSV52124073, COSV52127118; called by muse, mutect2, varscan2
- IL26 | c.111A>C p.T37= | Silent (SNP) | VAF 109/461 reads (24%) | catalogued as COSV57488794; called by muse, varscan2
- IL7R | c.372C>A p.T124= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as COSV100285999, COSV57407753; called by muse, mutect2, varscan2
- ISLR | c.1068G>A p.G356= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as COSV51433522; called by muse, mutect2
- KIF2B | c.714C>A p.V238= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV52129551, COSV52133682; called by muse, mutect2, varscan2
- KLHL28 | c.363G>T p.L121= | Silent (SNP) | VAF 27/140 reads (19%) | catalogued as COSV61887937; called by muse, mutect2, varscan2
- LHCGR | c.816G>T p.T272= | Silent (SNP) | VAF 66/197 reads (34%) | catalogued as COSV54296037; called by muse, mutect2, varscan2
- LHFPL1 | c.75C>A p.T25= | Silent (SNP) | VAF 165/687 reads (24%) | catalogued as COSV64333288; called by muse, varscan2
- LHX4 | c.258C>A p.G86= | Silent (SNP) | VAF 45/188 reads (24%) | catalogued as COSV55374810, COSV55378519; called by muse, mutect2, varscan2
- LILRB1 | c.1977C>A p.A659= (on ENST00000427581; = p.A608= on NM_006669.6) | Silent (SNP) | VAF 37/148 reads (25%) | catalogued as COSV61117428; called by muse, mutect2, varscan2
- LRBA | c.7200A>G p.S2400= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as rs1456691130, COSV63953568; called by muse, mutect2, varscan2
- LRP2 | c.600T>C p.Y200= | Silent (SNP) | VAF 26/227 reads (11%) | catalogued as COSV55550084; called by muse, mutect2, varscan2
- LRRIQ4 | c.249G>T p.L83= | Silent (SNP) | VAF 417/666 reads (63%) | catalogued as COSV61619003; called by muse, mutect2, varscan2
- LRRIQ4 | c.1287G>A p.R429= | Silent (SNP) | VAF 23/153 reads (15%) | catalogued as rs774639573, COSV61619009; called by muse, mutect2, varscan2
- MAP10 | c.1953G>T p.L651= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV69363389; called by muse, mutect2, varscan2
- MOSPD1 | c.501G>T p.V167= | Silent (SNP) | VAF 69/271 reads (25%) | catalogued as COSV66189269; called by muse, mutect2, varscan2
- MUSK | c.1473A>G p.T491= | Silent (SNP) | VAF 63/197 reads (32%) | catalogued as COSV51883803; called by muse, mutect2, varscan2
- MXRA5 | c.4938G>A p.P1646= | Silent (SNP) | VAF 152/620 reads (25%) | catalogued as rs138419461, COSV54232324; called by muse, varscan2
- NALCN | c.1617G>T p.T539= | Silent (SNP) | VAF 64/304 reads (21%) | catalogued as COSV51930762; called by muse, mutect2, varscan2
- NR5A1 | c.1260G>A p.L420= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV65294839; called by muse, mutect2, varscan2
- NRK | c.1167C>A p.P389= | Silent (SNP) | VAF 25/152 reads (16%) | catalogued as COSV99687001; called by muse, mutect2, varscan2
- OGDHL | c.1782G>T p.T594= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as COSV100934226; called by muse, mutect2, varscan2
- OR1C1 | c.774C>G p.V258= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as COSV68715660; called by muse, mutect2, varscan2
- OR1K1 | c.690C>A p.P230= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as COSV52956468; called by muse, mutect2, varscan2
- OR2T6 | c.48G>T p.G16= | Silent (SNP) | VAF 33/187 reads (18%) | catalogued as COSV63216090; called by muse, mutect2
- OVGP1 | c.324C>A p.T108= | Silent (SNP) | VAF 11/123 reads (9%) | catalogued as COSV63858232; called by muse, mutect2
- PCDHGA7 | c.1509C>A p.S503= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV53932710; called by muse, mutect2, varscan2
- PLP1 | c.426G>A p.L142= | Silent (SNP) | VAF 92/422 reads (22%) | catalogued as COSV58276290; called by muse, mutect2, varscan2
- PRG4 | c.2526T>A p.P842= | Silent (SNP) | VAF 129/630 reads (20%) | catalogued as COSV63355294; called by muse, mutect2, varscan2
- PRKD3 | c.42A>G p.V14= | Silent (SNP) | VAF 33/243 reads (14%) | catalogued as COSV52212666; called by muse, mutect2, varscan2
- PRRG3 | c.510G>T p.R170= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as COSV64850961; called by muse, mutect2, varscan2
- PTBP3 | c.243A>G p.P81= | Silent (SNP) | VAF 54/150 reads (36%) | catalogued as rs1156493219, COSV52957011; called by muse, mutect2, varscan2
- RBBP9 | c.231G>A p.G77= | Silent (SNP) | VAF 42/142 reads (30%) | catalogued as COSV61499852; called by muse, mutect2, varscan2
- RBM26 | c.1098G>A p.P366= | Silent (SNP) | VAF 38/124 reads (31%) | catalogued as rs367759226; called by muse, mutect2, varscan2
- RHBG | c.1194T>C p.F398= | Silent (SNP) | VAF 51/229 reads (22%) | catalogued as COSV54803883; called by muse, mutect2, varscan2
- RIC1 | c.2136A>G p.V712= | Silent (SNP) | VAF 44/176 reads (25%) | catalogued as rs777849861, COSV52608638; called by muse, mutect2, varscan2
- RIF1 | c.6864A>G p.T2288= | Silent (SNP) | VAF 63/253 reads (25%) | catalogued as COSV54615879; called by muse, mutect2, varscan2
- RPL10L | c.312C>A p.S104= | Silent (SNP) | VAF 28/135 reads (21%) | catalogued as COSV53559371; called by muse, mutect2, varscan2
- RTP5 | c.1596C>T p.A532= | Silent (SNP) | VAF 75/231 reads (32%) | catalogued as COSV58319674; called by muse, mutect2, varscan2
- SHC2 | c.1605G>T p.V535= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV52745382; called by muse, varscan2
- SLC1A7 | c.612G>T p.P204= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV65195037; called by muse, mutect2, varscan2
- SLC2A14 | c.891C>A p.S297= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs747868865, COSV61586287; called by muse, mutect2, varscan2
- SNAP91 | c.516G>A p.Q172= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV52120484; called by muse, mutect2, varscan2
- SPATA31A1 | c.2049C>A p.S683= | Silent (SNP) | VAF 86/756 reads (11%) | called by muse, mutect2, varscan2
- SPIRE2 | c.1149C>T p.A383= | Silent (SNP) | VAF 79/247 reads (32%) | catalogued as COSV65555282; called by muse, mutect2, varscan2
- SPTA1 | c.375C>A p.A125= | Silent (SNP) | VAF 82/321 reads (26%) | catalogued as COSV63751992; called by muse, mutect2, varscan2
- SYTL5 | c.162G>T p.G54= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as rs1215722683, COSV52900235; called by muse, varscan2
- TCEA1 | c.786A>T p.T262= | Silent (SNP) | VAF 38/134 reads (28%) | catalogued as rs374150495; called by muse, mutect2, varscan2
- TCL1B | c.126G>T p.S42= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as rs563494390, COSV61551921; called by muse, mutect2, varscan2
- TET1 | c.5319G>T p.V1773= | Silent (SNP) | VAF 41/196 reads (21%) | catalogued as COSV65384141; called by muse, mutect2, varscan2
- TMEM132E | c.1026G>C p.T342= (on ENST00000321639; = p.T432= on NM_001304438.2) | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs774833623, COSV58696331, COSV58696905; called by muse, mutect2, varscan2
- TMEM132E | c.1350C>T p.H450= (on ENST00000321639; = p.H540= on NM_001304438.2) | Silent (SNP) | VAF 83/331 reads (25%) | catalogued as COSV58696340; called by muse, mutect2, varscan2
- TRIML2 | c.837T>C p.D279= | Silent (SNP) | VAF 11/165 reads (7%) | catalogued as COSV58715693; called by muse, mutect2
- TSPYL2 | c.570G>T p.R190= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV60234538; called by mutect2, varscan2
- TTLL4 | c.537A>C p.T179= | Silent (SNP) | VAF 78/237 reads (33%) | catalogued as COSV51436032; called by muse, mutect2, varscan2
- UTP14A | c.1387C>T p.L463= | Silent (SNP) | VAF 188/772 reads (24%) | catalogued as COSV64086721; called by muse, mutect2, varscan2
- UTP14A | c.1803G>T p.G601= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV64086723; called by muse, mutect2, varscan2
- UTRN | c.6417G>T p.L2139= | Silent (SNP) | VAF 37/168 reads (22%) | catalogued as COSV62333267; called by muse, mutect2, varscan2
- VNN2 | c.1485C>A p.T495= | Silent (SNP) | VAF 25/173 reads (14%) | catalogued as COSV58472297; called by muse, mutect2, varscan2
- ZC2HC1C | c.195G>A p.L65= | Silent (SNP) | VAF 117/411 reads (28%) | catalogued as COSV53172350; called by muse, mutect2, varscan2
- ZNF567 | c.1503A>G p.G501= (on ENST00000536254 / NM_001322913.1; = p.G470= on NM_152603.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 24/150 reads (16%) | catalogued as COSV62445023; called by muse, mutect2, varscan2
- ZNF777 | c.2127G>T p.L709= | Silent (SNP) | VAF 43/134 reads (32%) | catalogued as COSV56097223; called by muse, mutect2, varscan2
- ZNF783 | c.537G>T p.L179= | Silent (SNP) | VAF 56/207 reads (27%) | catalogued as COSV65185242; called by muse, varscan2
- ZNF804A | c.1884A>G p.E628= | Silent (SNP) | VAF 68/284 reads (24%) | catalogued as COSV56445379; called by muse, mutect2, varscan2
- AC244258.1 | n.524C>A | RNA (SNP) | VAF 5/47 reads (11%) | called by mutect2, varscan2
- ADARB2 | c.1865-1484T>A | Intron (SNP) | VAF 17/78 reads (22%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852006 C>A | 3'Flank (SNP) | VAF 10/53 reads (19%) | catalogued as rs761377063; called by muse, mutect2, varscan2
- C1orf220 | n.522G>T | RNA (SNP) | VAF 38/133 reads (29%) | called by muse, mutect2, varscan2
- C7orf66 | n.138G>T | RNA (SNP) | VAF 18/107 reads (17%) | called by muse, mutect2, varscan2
- CCNQP1 | n.336C>G | RNA (SNP) | VAF 44/160 reads (28%) | catalogued as rs765464750; called by muse, mutect2, varscan2
- FYB1 | c.1907+1697_1907+1699del | Intron (DEL) | VAF 27/110 reads (25%) | called by mutect2, pindel, varscan2
- KCNIP4 | c.62-421192C>G | Intron (SNP) | VAF 24/70 reads (34%) | catalogued as COSV66169561; called by muse, mutect2, varscan2
- MBD1 | c.*70A>G | 3'UTR (SNP) | VAF 33/112 reads (29%) | catalogued as COSV99495785; called by muse, mutect2, varscan2
- NACA | c.70+3511C>T | Intron (SNP) | VAF 55/231 reads (24%) | catalogued as COSV100771171; called by muse, mutect2, varscan2
- PIKFYVE | c.322+307C>T | Intron (SNP) | VAF 7/40 reads (18%) | catalogued as COSV100010126; called by muse, mutect2, varscan2
- PTGER3 | c.1077+37C>G | Intron (SNP) | VAF 47/158 reads (30%) | catalogued as COSV100138510, COSV60695739; called by muse, mutect2, varscan2
- SNORD113-3 | n.67G>A | RNA (SNP) | VAF 102/271 reads (38%) | called by muse, mutect2, varscan2
- SNORD115-23 | n.54T>A | RNA (SNP) | VAF 78/400 reads (20%) | called by muse, varscan2
- TMPRSS11F | c.1015+2102C>A | Intron (SNP) | VAF 70/279 reads (25%) | catalogued as COSV100678303, COSV62466031; called by muse, mutect2, varscan2
- TPH2 | c.609-10876G>T | Intron (SNP) | VAF 33/143 reads (23%) | catalogued as COSV100421966; called by muse, mutect2, varscan2
